CGCI case HTMCP-03-06-02120 — HIV+ Tumor Molecular Characterization Project - Cervical Cancer (CGCI-HTMCP-CC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/167beb25-035b-432e-8698-c9eb9e2b6b75

Demographics
Sex at birth: female; Race: black or african american; Age at index: 60 years; Vital status: Dead; Days to death: 557 days (1.5 years).

Diagnoses (1)
1. Squamous cell carcinoma, nonkeratinizing, NOS: ICD-O-3 morphology code: 8072/3; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Year of diagnosis: 2014; Method of diagnosis: Biopsy; AJCC clinical T: T3b; AJCC clinical N: N0; AJCC clinical M: M0; FIGO stage: Stage IIIB; FIGO staging edition year: 2009; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 557 days (1.5 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 35 days; Days to treatment end: 55 days; Treatment dose: 45.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Treatment dose: 4500; Treatment anatomic sites: Pelvis.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (2 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Follow-up contacts recording only the day: day -1, day 55, day 557.

Molecular and laboratory tests
- CDKN2A (IHC): Positive.

Other clinical attributes
- Day -1: Comorbidities: HIV/AIDS.
- Day -1: Risk factors: HIV/AIDS.
- Day 0: Weight: 52.7 kg; Height: 161.5 cm; BMI: 20.2; CD4 count: 300; Haart treatment indicator: No; HIV viral load: 32841; Hormonal contraceptive use: Never Used; Hysterectomy type: Not Performed; Menopause status: Postmenopausal; Pregnant at diagnosis: No.
- Day 0: Nadir CD4 count: 300.
- Day 0: Pregnancy outcome: Miscarriage.
- Day 0: Cdc hiv risk factors: Heterosexual Contact.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (4 samples)
- Samples HTMCP-03-06-02120-01A, HTMCP-03-06-02120-01B (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-03-06-02120-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-03-06-02120-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 13; Pregnancies count miscarriage: 2; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Total pregnancy count: 15; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Squamous Cell Carcinoma, Non-Keratinizing; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Hysterectomy Performed Ind-3: No; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: Haart therapy at diagnosis: No; Haart therapy prior to diagnosis: No.
- Follow-up form 1, Treatment, Radiation therapy info: Radiation therapy xrt type: External beam radiation.
- Follow-up form 1, Treatment, Concurrent prescription treatment info: Chemo concurrent reason not given: Not done per treating physicians discretion.
- Treatments, Treatment: Therapy regimen: Initial; Treatment type: Radiation Therapy; Radiation therapy end: Yes; Radiation therapy total dosage: 45.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02120-01A-01R-5099:
- % tumour top: 70
- % tumour bottom: 70

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02120-01A-01D-5099:
- % tumour top: 70
- % tumour bottom: 70

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02120-10A-01D-5099:
- % tumour top: 0
- % tumour bottom: 0

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02120-01B-01S-6335:
- % tumour top: 80

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02120-01B-01E-6335:
- % tumour top: 80

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementSpreadsheet03_20191126.xlsx, for sample HTMCP-03-06-02120-01A-02R-5099:
- % tumour top: 70
- % tumour bottom: 70

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementSpreadsheet03_20191126.xlsx, for sample HTMCP-03-06-02120-01A-03R-5099:
- % tumour top: 70
- % tumour bottom: 70
